CPTAC case C3N-02681 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27623cf1-4afb-44a1-a194-b761579c439b

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Dead; Days to death: 1,009 days (2.8 years); Year of death: 2020; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 65.7 years (23,981 days); Year of diagnosis: 2017; Days to last known disease status: 1,009 days (2.8 years); Days to last follow up: 1,009 days (2.8 years).
   Pathology details: Greatest tumor dimension: 5 cm.

Follow-up (2 entries)
- Days to follow up: 1,009 days (2.8 years); Karnofsky performance status: 0; ECOG performance status: 5.
- Follow-up contacts recording only the day: day 365, day 771.

Other clinical attributes
- Weight: 79 kg; Height: 165 cm; BMI: 29.02.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02681-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -26 days; Initial weight: 299 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02681-22: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-02681-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -26 days; Method of sample procurement: Blood Draw.
